Somatic mutation profile of tumor specimen ALCH-B1L5-TTP1-A (aliquot ALCH-B1L5-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1L5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.3 years (25,306 days).
Specimen ALCH-B1L5-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d0adb83-9871-4f0a-b5eb-e00384a8f423.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1L5-NB1-A (Blood Derived Normal), aliquot ALCH-B1L5-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ecd3661f-3016-4f84-9545-da248b3de3c2

The open-access MAF lists 282 somatic variants for this specimen: 202 protein-altering or splice-affecting, 56 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 178, Silent 56, Nonsense Mutation 17, Intron 10, RNA 6, 5'UTR 3, 3'UTR 3, Splice Region 3, Frame Shift Del 2, Splice Site 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 46/253 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 20/194 reads (10%) | catalogued as rs879253911, CM941328, COSV52694461, COSV52816009, COSV53014483, COSV53470757; ClinVar: pathogenic; called by muse, mutect2
- AC127029.3 | c.625G>C p.V209L | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as rs377027593; called by muse, mutect2, varscan2
- ADAMTS16 | c.2328C>G p.I776M | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1338095625, COSV99942985; called by muse, mutect2
- AFF2 | c.2543C>A p.A848D | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.224); catalogued as COSV53985862; called by muse, mutect2
- C4orf54 | c.3011C>T p.P1004L | Missense Mutation (SNP) | VAF 36/454 reads (8%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.992); catalogued as rs898307213; called by muse, mutect2
- C6orf118 | c.1031C>A p.A344D | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100024747; called by muse, mutect2
- CDH10 | c.2311C>G p.R771G | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52575394; called by muse, mutect2
- CDH6 | c.62C>G p.S21* | Nonsense Mutation (SNP) | VAF 16/312 reads (5%) | catalogued as COSV54076383; called by muse, mutect2
- CDH7 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779691485, COSV100543084; called by mutect2, varscan2
- CSN2 | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV100778808, COSV61992317; called by muse, mutect2
- DDX60 | c.5049G>T p.L1683F | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751028354, COSV101190530; called by muse, mutect2, varscan2
- DLG1 | c.2523G>T p.M841I (on ENST00000419354 / NM_001290983.1; = p.M863I on NM_004087.2) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.135); catalogued as COSV58383414, COSV58386631; called by muse, mutect2, varscan2
- DRD5 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs372277553, COSV58578583; called by muse, mutect2
- DSCAML1 | c.3225G>T p.Q1075H (on ENST00000321322; = p.Q1015H on NM_020693.4) | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV58390038; called by muse, mutect2, varscan2
- EDAR | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 35/309 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs1266264474; called by muse, mutect2, varscan2
- ERBB4 | c.581C>A p.T194N | Missense Mutation (SNP) | VAF 60/684 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53545732; called by muse, mutect2
- FAM47B | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.774); catalogued as COSV61456011; called by muse, mutect2, varscan2
- FAM71E2 | c.985C>A p.L329M | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.648); catalogued as COSV99214821; called by muse, varscan2
- FCRL5 | c.98C>G p.T33R | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.593); catalogued as rs760601224; called by muse, mutect2, varscan2
- FMN2 | c.2722C>G p.L908V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.027); catalogued as COSV100148114; called by mutect2, varscan2
- GABRA2 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as rs1388750064; called by muse, mutect2
- GPR3 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs745929629; called by muse, mutect2
- HECW2 | c.3342G>T p.K1114N | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs752382911; called by muse, varscan2
- HIVEP2 | c.3362A>G p.H1121R | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.15); catalogued as rs1205975100; called by muse, mutect2
- INMT | c.691G>C p.D231H | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.764); catalogued as rs1437985715; called by muse, mutect2
- IREB2 | c.1840G>T p.E614* | Nonsense Mutation (SNP) | VAF 6/101 reads (6%) | catalogued as COSV51922485; called by muse, mutect2
- ITGAV | c.2632G>T p.A878S | Missense Mutation (SNP) | VAF 23/265 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1459652768; called by muse, mutect2
- KIF2B | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 16/247 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52129098; called by muse, mutect2
- KIR3DL2 | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 30/476 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs879153275; called by muse, mutect2
- KRTAP1-4 | c.80C>A p.P27Q | Missense Mutation (SNP) | VAF 44/399 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV100721374; called by muse, mutect2, varscan2
- MADCAM1 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs1166652828, COSV53129127; called by muse, mutect2, varscan2
- MRGPRX4 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); catalogued as COSV58590058; called by muse, mutect2, varscan2
- NLRP11 | c.546C>A p.Y182* | Nonsense Mutation (SNP) | VAF 22/228 reads (10%) | catalogued as rs779869916, COSV100789619; called by muse, mutect2
- OR2W3 | c.224C>A p.T75N | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV100831588, COSV64457532; called by muse, mutect2, varscan2
- OR5AR1 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 43/397 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs760402764, COSV57254278; called by muse, mutect2, varscan2
- OR5D18 | c.782G>T p.C261F | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100450609; called by muse, mutect2, varscan2
- OR8A1 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs1311670471; called by muse, mutect2
- PADI1 | c.280G>T p.V94F | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs766185297; called by muse, mutect2, varscan2
- PASD1 | c.1250G>T p.R417L | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV64853917; called by muse, mutect2
- PRRG1 | c.370C>G p.Q124E | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as COSV101068967; called by muse, mutect2
- SLC22A12 | c.274C>A p.R92S | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.376); catalogued as CM1511162; called by muse, mutect2, varscan2
- SLFN13 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 32/201 reads (16%) | catalogued as COSV53193028, COSV53194707; called by muse, mutect2, varscan2
- SLITRK1 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs1227183187; called by muse, mutect2
- SPAM1 | c.704A>G p.N235S | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.076); catalogued as rs1185428429; called by muse, varscan2
- SPTA1 | c.6897C>A p.C2299* | Nonsense Mutation (SNP) | VAF 22/474 reads (5%) | catalogued as COSV63755124; called by muse, mutect2
- TM7SF3 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 64/878 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.12); catalogued as rs1290772844; called by muse, mutect2
- TP73 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 52/488 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1486664777; called by muse, mutect2, varscan2
- USH1C | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.243); catalogued as rs754055631, COSV50014997; called by muse, mutect2
- VAT1L | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV56818855; called by muse, mutect2
- VCAN | c.92C>A p.P31Q | Missense Mutation (SNP) | VAF 27/263 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV54099444; called by muse, mutect2, varscan2
- VCL | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 37/331 reads (11%) | catalogued as COSV99280596; called by muse, mutect2, varscan2
- WAS | c.756G>C p.W252C | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM064359; called by muse, mutect2
- ZNF282 | c.91C>G p.L31V | Missense Mutation (SNP) | VAF 29/305 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.031); catalogued as rs1365859151; called by muse, mutect2
- ZNF479 | c.631A>T p.K211* | Nonsense Mutation (SNP) | VAF 8/134 reads (6%) | catalogued as COSV100482665; called by muse, mutect2
- ZNF804A | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100169627; called by muse, mutect2
- ZNF831 | c.1123G>T p.G375W | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs770198523, COSV64042227; called by muse, mutect2, varscan2
- ABCC11 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCC8 | c.1818-6G>T | Splice Region (SNP) | VAF 28/227 reads (12%) | called by muse, mutect2, varscan2
- ACKR1 | c.497C>A p.T166N | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.894); called by muse, mutect2
- ADAMTS1 | c.1083G>T p.L361F | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ADAMTS2 | c.1777C>A p.P593T | Missense Mutation (SNP) | VAF 28/331 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS3 | c.2407G>T p.D803Y | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.964); called by muse, mutect2
- ADAMTSL3 | c.3151A>T p.S1051C | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.215); called by muse, mutect2
- ANK2 | c.7216C>T p.P2406S | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.116); called by muse, mutect2
- ANKRD50 | c.3062G>C p.W1021S | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- ANO5 | c.2701A>T p.I901F | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- APOB | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 33/389 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2
- ARC | c.1105C>A p.H369N | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.005); called by muse, varscan2
- ASXL3 | c.752T>A p.I251K | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ATAD3A | c.1807G>T p.D603Y | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.734); called by muse, mutect2
- ATG2B | c.2737-1G>T p.X913_splice | Splice Site (SNP) | VAF 9/109 reads (8%) | called by muse, mutect2
- BIVM-ERCC5 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.08); called by muse, varscan2
- BTBD17 | c.698C>A p.A233E | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CA7 | c.477G>A p.M159I | Missense Mutation (SNP) | VAF 20/227 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.116); called by muse, mutect2
- CBFA2T3 | c.937C>A p.H313N | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- CCR3 | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- CDC25A | c.528G>C p.Q176H | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDC25B | c.646G>C p.E216Q (on ENST00000245960 / NM_021873.3; = p.E202Q on NM_004358.4) | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.688); called by muse, mutect2
- CLEC12B | c.236G>C p.S79T | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.012); called by muse, mutect2
- CRIM1 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 15/406 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- CSH2 | c.44T>A p.L15Q | Missense Mutation (SNP) | VAF 55/594 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD2 | c.706C>A p.L236M | Missense Mutation (SNP) | VAF 38/412 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.811); called by muse, mutect2
- CXADR | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 13/175 reads (7%) | called by muse, mutect2
- CYP8B1 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 17/250 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- DCHS2 | c.1486C>A p.P496T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- DCUN1D5 | c.301T>G p.F101V | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DCX | c.868C>A p.P290T | Missense Mutation (SNP) | VAF 54/578 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2
- DGKI | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); called by muse, mutect2
- DHX57 | c.35del p.G12Afs*70 | Frame Shift Del (DEL) | VAF 13/136 reads (10%) | called by pindel, varscan2
- DIP2C | c.1517G>T p.S506I | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- DLC1 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.005); called by muse, mutect2
- DMD | c.9045C>A p.S3015R | Missense Mutation (SNP) | VAF 43/423 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH14 | c.4967T>C p.I1656T (on ENST00000445597; = p.I2061T on NM_001367479.1) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.015); called by muse, mutect2
- DNAH17 | c.10456A>T p.I3486F | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- DPP10 | c.1752G>T p.W584C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DRD1 | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DUSP26 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.023); called by muse, mutect2
- EFTUD2 | c.2548C>G p.L850V | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EML5 | c.1888G>T p.D630Y | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPHA10 | c.2095G>T p.G699C | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- EPPK1 | c.4802C>A p.A1601D | Missense Mutation (SNP) | VAF 30/412 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- EYA1 | c.966G>T p.E322D | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.181); called by muse, mutect2
- EYS | c.3133G>T p.D1045Y | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- FANCA | c.3169C>T p.Q1057* | Nonsense Mutation (SNP) | VAF 27/181 reads (15%) | called by muse, mutect2, varscan2
- FARS2 | c.214A>C p.T72P | Missense Mutation (SNP) | VAF 65/297 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FAT1 | c.5149G>A p.G1717R | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT3 | c.3954G>T p.Q1318H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.878); called by muse, varscan2
- FBXO31 | c.610G>A p.V204M | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FFAR4 | c.1010A>G p.Y337C | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FNIP1 | c.2185del p.V729Wfs*26 | Frame Shift Del (DEL) | VAF 10/107 reads (9%) | called by mutect2, pindel
- FTL | c.365C>G p.T122R | Missense Mutation (SNP) | VAF 40/487 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.449); called by muse, mutect2
- GAS2L2 | c.1028C>A p.P343H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- GCN1 | c.4477C>A p.H1493N | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- GDF5 | c.694G>C p.D232H | Missense Mutation (SNP) | VAF 23/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- GHR | c.1850C>A p.P617H | Missense Mutation (SNP) | VAF 20/375 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); called by muse, mutect2
- GPR75 | c.829T>A p.Y277N | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.637); called by muse, mutect2
- GRIA4 | c.1178T>C p.M393T | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- GRM8 | c.2075C>A p.P692Q | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HNRNPUL1 | c.1412G>T p.R471L | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- HOMER3 | c.595C>G p.L199V | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HTR4 | c.194C>G p.A65G | Missense Mutation (SNP) | VAF 12/186 reads (6%) | PolyPhen possibly damaging (0.578); called by muse, mutect2
- IGHV4-39 | c.7C>A p.L3I | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.022); called by muse, mutect2
- IGSF9B | c.2626G>T p.G876C | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- IMPG1 | c.212C>A p.S71Y | Missense Mutation (SNP) | VAF 22/307 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- IRAK2 | c.980A>G p.H327R | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2
- KCNJ12 | c.344C>A p.A115D | Missense Mutation (SNP) | VAF 25/398 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.102); called by muse, mutect2
- KCNT1 | c.618+3G>C | Splice Region (SNP) | VAF 36/283 reads (13%) | called by muse, mutect2, varscan2
- KIF26A | c.4624C>A p.P1542T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.438); called by muse, varscan2
- KMT2C | c.10541C>T p.S3514L | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2
- KRTAP4-6 | c.560C>A p.P187Q | Missense Mutation (SNP) | VAF 38/407 reads (9%) | SIFT deleterious (0.01); called by muse, mutect2
- L1CAM | c.1386C>A p.D462E | Missense Mutation (SNP) | VAF 33/275 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- LPO | c.953G>T p.S318I | Missense Mutation (SNP) | VAF 39/358 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- LRATD1 | c.108C>G p.F36L | Missense Mutation (SNP) | VAF 35/474 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.482); called by muse, mutect2
- MAGEA6 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 22/529 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.524); called by muse, mutect2
- MAT1A | c.860A>T p.Y287F | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MID2 | c.1658G>T p.G553V | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.206); called by muse, varscan2
- MORC4 | c.2014G>T p.E672* | Nonsense Mutation (SNP) | VAF 6/142 reads (4%) | called by muse, mutect2
- MPP5 | c.1543A>G p.T515A | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2
- MROH2A | c.3785G>T p.R1262L | Missense Mutation (SNP) | VAF 25/324 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.039); called by muse, mutect2
- MS4A6E | c.395T>A p.F132Y | Missense Mutation (SNP) | VAF 30/488 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); called by muse, mutect2
- MTX1 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 19/255 reads (7%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYBPC2 | c.680A>T p.E227V | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MYH3 | c.4273G>T p.E1425* | Nonsense Mutation (SNP) | VAF 30/314 reads (10%) | called by muse, mutect2
- NCOR2 | c.1742G>C p.R581P | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEB | c.12448A>G p.K4150E | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2
- NEMP2 | c.1051C>G p.L351V | Missense Mutation (SNP) | VAF 12/311 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NPHS1 | c.635G>T p.R212M | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.153); called by muse, mutect2
- OPN1MW | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 28/414 reads (7%) | called by muse, mutect2
- OR10J5 | c.761C>A p.A254D | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- OR56B4 | c.103C>A p.L35M | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- OTOG | c.1438G>T p.G480W | Missense Mutation (SNP) | VAF 12/265 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OTOP1 | c.1788C>G p.F596L | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTUD7A | c.1554C>A p.D518E (on ENST00000307050 / NM_001382637.1; = p.D511E on NM_130901.3) | Missense Mutation (SNP) | VAF 68/623 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PAEP | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); called by muse, mutect2
- PARD3 | c.1333A>T p.T445S | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH11X | c.3400G>C p.E1134Q | Missense Mutation (SNP) | VAF 35/485 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.925); called by muse, mutect2
- PCDHA6 | c.1787C>A p.A596E | Missense Mutation (SNP) | VAF 31/633 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PCDHB10 | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDE6B | c.870G>T p.W290C | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- PDGFRA | c.293A>G p.Y98C | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHG2 | c.784G>C p.G262R | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLXNB3 | c.311C>A p.P104Q | Missense Mutation (SNP) | VAF 39/308 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PREP | c.674A>T p.D225V (on ENST00000369110; = p.D291V on NM_002726.5) | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.188); called by muse, mutect2
- PSMA4 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PSMC5 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 24/333 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPRB | c.3890G>T p.W1297L | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- RGS12 | c.1545G>T p.L515F | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- RNF150 | c.152C>G p.P51R | Missense Mutation (SNP) | VAF 32/304 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RP1 | c.4131C>A p.D1377E | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.1); called by mutect2, varscan2
- RYR2 | c.1444C>A p.L482M | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SAMD9 | c.2565G>C p.Q855H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- SCN3A | c.4897C>A p.R1633S | Missense Mutation (SNP) | VAF 36/456 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2
- SEL1L3 | c.1766A>T p.D589V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- SHANK1 | c.5520G>T p.W1840C | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC29A3 | c.735G>T p.M245I | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLC6A19 | c.1448C>A p.S483Y | Missense Mutation (SNP) | VAF 39/609 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); called by muse, mutect2
- SLCO2B1 | c.1142T>C p.V381A | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- SORCS1 | c.2188T>G p.C730G | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPOCK1 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.099); called by muse, mutect2
- STAG3 | c.2133-6C>A | Splice Region (SNP) | VAF 20/147 reads (14%) | called by muse, mutect2, varscan2
- TBX18 | c.659C>G p.P220R | Missense Mutation (SNP) | VAF 29/269 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TIMP3 | c.334A>T p.K112* | Nonsense Mutation (SNP) | VAF 19/360 reads (5%) | called by muse, mutect2
- TMEM18 | c.265A>T p.R89W | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TNIP1 | c.1224G>T p.Q408H | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.178); called by muse, mutect2
- TPM3 | c.139A>T p.M47L | Missense Mutation (SNP) | VAF 87/539 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAV3 | c.26T>A p.L9H | Missense Mutation (SNP) | VAF 27/271 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2
- TRBV7-1 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- TREML2 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.321); called by muse, mutect2
- UBLCP1 | c.938C>G p.S313* | Nonsense Mutation (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2, varscan2
- UNC5C | c.2006T>A p.L669Q | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- USH2A | c.1715G>T p.C572F | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VGLL1 | c.399C>A p.F133L | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.037); called by muse, mutect2
- VPS9D1 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 16/89 reads (18%) | called by muse, mutect2, varscan2
- WNT8A | c.971G>A p.C324Y | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- XPO7 | c.166-2A>T p.X56_splice | Splice Site (SNP) | VAF 18/132 reads (14%) | called by muse, varscan2
- ZNF160 | c.2313G>T p.R771S | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF160 | c.2312G>T p.R771M | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZNF26 | c.775G>T p.G259C | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.749); called by mutect2, varscan2
- ZSCAN1 | c.971A>T p.E324V | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- ZSCAN9 | c.916A>G p.I306V | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZSWIM2 | c.405C>A p.Y135* | Nonsense Mutation (SNP) | VAF 12/208 reads (6%) | called by muse, mutect2
- ABCB5 | c.3303G>A p.V1101= (on ENST00000404938 / NM_001163941.2; = p.V656= on NM_178559.6) | Silent (SNP) | VAF 30/306 reads (10%) | called by muse, mutect2
- ADAMTS18 | c.1398C>T p.T466= | Silent (SNP) | VAF 23/261 reads (9%) | catalogued as rs372974892; ClinVar: likely benign; called by muse, mutect2
- ADGRL3 | c.2841G>C p.V947= (on ENST00000506720 / NM_001322402.2; = p.V879= on NM_015236.6) | Silent (SNP) | VAF 35/289 reads (12%) | called by muse, mutect2, varscan2
- AK8 | c.1173G>A p.L391= | Silent (SNP) | VAF 10/152 reads (7%) | catalogued as rs1201117559; called by muse, mutect2
- ANKAR | c.3009A>G p.P1003= | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2
- ANKRD17 | c.5982C>T p.V1994= | Silent (SNP) | VAF 24/574 reads (4%) | called by muse, mutect2
- CCDC174 | c.117A>T p.G39= | Silent (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- COL25A1 | c.1413C>A p.I471= | Silent (SNP) | VAF 12/115 reads (10%) | called by muse, mutect2
- CYP19A1 | c.606C>G p.L202= | Silent (SNP) | VAF 10/145 reads (7%) | called by muse, mutect2
- DOK6 | c.315G>A p.K105= | Silent (SNP) | VAF 26/338 reads (8%) | catalogued as rs1174145015; called by muse, mutect2
- FAM71E2 | c.1650G>T p.A550= | Silent (SNP) | VAF 17/140 reads (12%) | catalogued as COSV58483292; called by muse, mutect2, varscan2
- FAM83C | c.84G>T p.L28= | Silent (SNP) | VAF 14/188 reads (7%) | called by muse, mutect2
- FLNC | c.6705C>A p.G2235= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- FOXG1 | c.1146C>A p.A382= | Silent (SNP) | VAF 48/676 reads (7%) | catalogued as COSV57395750; called by muse, mutect2
- FOXP1 | c.345C>T p.I115= | Silent (SNP) | VAF 22/312 reads (7%) | catalogued as rs1269740658; called by muse, mutect2
- FRMPD2 | c.2310C>A p.G770= | Silent (SNP) | VAF 31/252 reads (12%) | called by muse, mutect2, varscan2
- GZMA | c.672G>A p.G224= | Silent (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- HLX | c.1287C>A p.G429= | Silent (SNP) | VAF 18/230 reads (8%) | called by muse, mutect2
- HOMER3 | c.597G>T p.L199= | Silent (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- HSPA12A | c.1479G>T p.A493= | Silent (SNP) | VAF 14/133 reads (11%) | catalogued as rs782001720; called by muse, mutect2
- IGHMBP2 | c.324G>T p.R108= | Silent (SNP) | VAF 17/165 reads (10%) | called by muse, mutect2, varscan2
- IGSF3 | c.3186C>G p.L1062= (on ENST00000369486 / NM_001007237.3; = p.L1082= on NM_001542.4) | Silent (SNP) | VAF 11/196 reads (6%) | catalogued as COSV59599929; called by muse, mutect2
- IQCH | c.2346C>T p.F782= | Silent (SNP) | VAF 38/409 reads (9%) | called by muse, mutect2
- ITGB2 | c.609C>A p.A203= | Silent (SNP) | VAF 35/289 reads (12%) | called by muse, mutect2, varscan2
- JPH2 | c.2070C>A p.L690= | Silent (SNP) | VAF 51/431 reads (12%) | called by muse, mutect2, varscan2
- KIF1A | c.657C>T p.A219= | Silent (SNP) | VAF 21/256 reads (8%) | catalogued as rs531993959; ClinVar: likely benign; called by muse, mutect2
- KRT34 | c.1077G>C p.L359= | Silent (SNP) | VAF 23/313 reads (7%) | catalogued as rs144311709; called by muse, mutect2
- KRTAP5-7 | c.150A>T p.P50= | Silent (SNP) | VAF 36/414 reads (9%) | catalogued as rs1211833063; called by muse, mutect2
- L1CAM | c.3006T>G p.G1002= | Silent (SNP) | VAF 17/344 reads (5%) | called by muse, mutect2
- LPAR3 | c.960C>T p.P320= | Silent (SNP) | VAF 23/233 reads (10%) | called by muse, mutect2, varscan2
- MID2 | c.1971C>T p.L657= | Silent (SNP) | VAF 16/316 reads (5%) | called by muse, mutect2
- MID2 | c.1972C>T p.L658= | Silent (SNP) | VAF 16/314 reads (5%) | called by muse, mutect2
- MMP3 | c.939C>T p.H313= | Silent (SNP) | VAF 30/319 reads (9%) | catalogued as rs781929014; called by muse, mutect2
- NPC1 | c.1392T>C p.L464= | Silent (SNP) | VAF 13/240 reads (5%) | called by muse, mutect2
- OR5L1 | c.336C>G p.V112= | Silent (SNP) | VAF 31/249 reads (12%) | called by muse, mutect2, varscan2
- OR9Q2 | c.717C>A p.S239= | Silent (SNP) | VAF 13/124 reads (10%) | catalogued as COSV61111987; called by muse, mutect2
- PCDHGA2 | c.1677G>A p.A559= | Silent (SNP) | VAF 38/634 reads (6%) | catalogued as rs772392717, COSV53960042; called by muse, mutect2
- PLXNA3 | c.2553C>A p.P851= | Silent (SNP) | VAF 38/424 reads (9%) | called by muse, mutect2
- PRDM2 | c.2814T>A p.V938= | Silent (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- RUNX1T1 | c.1416G>A p.E472= (on ENST00000265814 / NM_001198628.1; = p.E445= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/232 reads (8%) | called by muse, mutect2
- RYR2 | c.1443C>A p.A481= | Silent (SNP) | VAF 29/264 reads (11%) | catalogued as rs1032338127, COSV63684265; called by muse, mutect2, varscan2
- RYR2 | c.2808G>T p.S936= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs1057521205; ClinVar: likely benign; called by muse, mutect2
- SCRT1 | c.855C>T p.F285= | Silent (SNP) | VAF 11/240 reads (5%) | catalogued as COSV59780900; called by muse, mutect2
- SLC25A52 | c.522G>T p.L174= (on ENST00000672005; = p.L164= on NM_001034172.4) | Silent (SNP) | VAF 10/248 reads (4%) | catalogued as rs1359935196, COSV52501416; called by muse, mutect2
- SOGA3 | c.1845G>C p.L615= | Silent (SNP) | VAF 17/503 reads (3%) | called by muse, mutect2
- SPATA31A6 | c.3396C>A p.V1132= | Silent (SNP) | VAF 24/435 reads (6%) | called by muse, mutect2
- STK39 | c.1362C>T p.L454= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as rs776942723; called by muse, mutect2, varscan2
- TBX21 | c.315C>A p.G105= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs761496612; called by mutect2, varscan2
- TENM1 | c.552A>G p.P184= | Silent (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- TMEM176B | c.309G>T p.G103= | Silent (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
- UNC80 | c.2661G>T p.V887= | Silent (SNP) | VAF 9/140 reads (6%) | called by muse, mutect2
- USP2 | c.1569A>T p.L523= | Silent (SNP) | VAF 18/194 reads (9%) | called by muse, mutect2
- VPS51 | c.1020C>T p.F340= | Silent (SNP) | VAF 29/348 reads (8%) | catalogued as rs767698867, COSV54206309; called by muse, mutect2
- VPS51 | c.1381C>T p.L461= | Silent (SNP) | VAF 28/688 reads (4%) | called by muse, mutect2
- VWCE | c.867T>G p.P289= | Silent (SNP) | VAF 23/260 reads (9%) | catalogued as rs769181650; called by muse, mutect2
- YDJC | c.123C>T p.V41= | Silent (SNP) | VAF 7/82 reads (9%) | called by muse, mutect2
- AC074085.2 | n.64C>A | RNA (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- AC116366.2 | c.-638+10987G>A | Intron (SNP) | VAF 13/390 reads (3%) | catalogued as rs1422077276; called by muse, mutect2
- DENND10P1 | n.492G>T | RNA (SNP) | VAF 25/247 reads (10%) | called by muse, mutect2, varscan2
- EPHA10 | c.1491+661A>T | Intron (SNP) | VAF 13/134 reads (10%) | called by muse, mutect2, varscan2
- EPS8L1 | c.430-61G>A | Intron (SNP) | VAF 17/198 reads (9%) | catalogued as COSV52385881; called by muse, mutect2
- FRMD8P1 | n.314G>T | RNA (SNP) | VAF 22/344 reads (6%) | catalogued as rs761443233; called by muse, mutect2
- FTH1 | chr11:61959742 G>C | 3'Flank (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- GUSB | c.1245-9G>T | Intron (SNP) | VAF 16/159 reads (10%) | called by muse, mutect2
- IL10 | c.378+14C>A | Intron (SNP) | VAF 35/230 reads (15%) | called by muse, mutect2, varscan2
- KEL | c.*70G>T | 3'UTR (SNP) | VAF 15/128 reads (12%) | called by muse, mutect2, varscan2
- LCN12 | c.-12G>A | 5'UTR (SNP) | VAF 28/269 reads (10%) | catalogued as rs1340071919; called by muse, mutect2, varscan2
- NFYC | c.388-783G>C | Intron (SNP) | VAF 11/89 reads (12%) | called by muse, mutect2, varscan2
- OBSCN | c.18662-2670G>T | Intron (SNP) | VAF 22/694 reads (3%) | catalogued as rs1333630318, COSV52740112; called by muse, mutect2
- PCNX1 | c.*41T>A | 3'UTR (SNP) | VAF 13/136 reads (10%) | called by muse, mutect2
- POU2F3 | c.362-1234G>C | Intron (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2
- RAD51D | c.-123C>G | 5'UTR (SNP) | VAF 9/130 reads (7%) | called by muse, mutect2
- RALGAPA1 | c.3106+42G>T | Intron (SNP) | VAF 11/136 reads (8%) | called by muse, mutect2
- RECQL5 | chr17:75667333 G>C | 5'Flank (SNP) | VAF 15/212 reads (7%) | catalogued as rs1249803826; called by muse, mutect2
- SKP1P2 | n.386G>T | RNA (SNP) | VAF 12/112 reads (11%) | called by muse, varscan2
- SLC38A7 | c.270+16G>T | Intron (SNP) | VAF 17/137 reads (12%) | called by muse, mutect2, varscan2
- SNORC | c.-52C>T | 5'UTR (SNP) | VAF 12/166 reads (7%) | called by muse, mutect2
- UBE2DNL | n.369G>A | RNA (SNP) | VAF 27/342 reads (8%) | called by muse, mutect2
- UBTFL2 | n.523C>A | RNA (SNP) | VAF 14/184 reads (8%) | called by muse, mutect2
- UMPS | c.*4114A>G | 3'UTR (SNP) | VAF 8/128 reads (6%) | catalogued as rs1202621240; called by muse, mutect2
